MMRF case MMRF_1595 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/0d92dbf1-32cb-417a-ac08-f1595aa4a70a

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 73 years; Vital status: Dead; Days to death: 796 days (2.2 years); Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 73.8 years (26,950 days); ISS stage: III; Days to last known disease status: 796 days (2.2 years); Days to last follow up: 796 days (2.2 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 107 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 107 days; Days to treatment end: 162 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 179 days; Days to treatment end: 227 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 796.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -13 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 398 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.82 mg/dL; Immunoglobulin G 4.78 g/L; Immunoglobulin A 0.0667 g/L; Immunoglobulin M 0.29 g/L; Beta 2 Microglobulin 7.27 µg/mL; Lactate Dehydrogenase 4.52 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.89 ×10⁹/L; Platelets 114 ×10⁹/L; Creatinine 102 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.23 mmol/L; Albumin 31 g/L; Total Protein 6.4 g/dL; Glucose 7.87 mmol/L; C-Reactive Protein 10.9 mg/dL.
- Day 85 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 16.7 mg/dL; Immunoglobulin G 5.28 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.26 g/L; Beta 2 Microglobulin 2.6 µg/mL; Lactate Dehydrogenase 2.53 µkat/L; Hemoglobin 5.7 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 1.13 ×10⁹/L; Platelets 69 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.03 mmol/L; Albumin 30 g/L; Total Protein 4.9 g/dL; Glucose 5.5 mmol/L.
- Day 179 (ECOG 1): M Protein 0 g/dL; Immunoglobulin G 11.1 g/L; Immunoglobulin A 0.04 g/L; Immunoglobulin M 0.49 g/L; Hemoglobin 5.46 mmol/L; Leukocytes 2.2 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 98 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.08 mmol/L; Albumin 37 g/L; Total Protein 6 g/dL; Glucose 4.9 mmol/L.
- Day 257 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.92 mg/dL; Immunoglobulin G 10.7 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.44 g/L; Beta 2 Microglobulin 4.06 µg/mL; Hemoglobin 5.39 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 89 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.15 mmol/L; Albumin 34 g/L; Total Protein 6 g/dL; Glucose 7.54 mmol/L.
- Day 342 (ECOG 1): Hemoglobin 6.2 mmol/L; Leukocytes 2.5 ×10⁹/L; Platelets 82 ×10⁹/L; Creatinine 131 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.08 mmol/L; Albumin 32 g/L; Total Protein 5.7 g/dL; Glucose 10.6 mmol/L.
- Day 442 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.34 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.13 mg/dL; Hemoglobin 5.15 mmol/L; Leukocytes 4.7 ×10⁹/L; Platelets 92 ×10⁹/L; Creatinine 138 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.08 mmol/L; Albumin 33 g/L; Total Protein 6.1 g/dL; Glucose 5.83 mmol/L.
- Day 504: M Protein 0 g/dL; Hemoglobin 5.64 mmol/L; Leukocytes 3.9 ×10⁹/L; Platelets 122 ×10⁹/L; Creatinine 134 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.15 mmol/L; Albumin 38 g/L; Total Protein 6.3 g/dL; Glucose 9.57 mmol/L.
- Day 623: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 18 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.52 mg/dL; Immunoglobulin G 11.8 g/L; Immunoglobulin A 0.04 g/L; Immunoglobulin M 0.79 g/L; Hemoglobin 6.45 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 5.3 ×10⁹/L; Platelets 170 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.05 mmol/L; Albumin 33 g/L; Total Protein 5.7 g/dL; Glucose 9.96 mmol/L.

Other clinical attributes
- Day -13: Weight: 65 kg; Height: 177 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Colorectal Cancer.
- Relative with cancer history: yes; Relationship type: Father; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1595_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -13 days.
- Sample MMRF_1595_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -13 days.
